Surgical pathology report (de-identified scan), TCGA case TCGA-BA-4077, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-4077-01B (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REVISED REPORT

Surgical Pathology Report

* Amended *

Amendments:

Amended:

Reason: Additional Information

Comment: FSF, F additional line.

Previous Signout Date: [REDACTED]

Diagnosis:

FSA: Lymph nodes, pretracheal, biopsy.

- No metastatic carcinoma identified (0/2).

FSB: Periosteum, mental, biopsy.

- Skeletal muscle, no invasive carcinoma identified.

FSC: Right carotid sheath, biopsy.

- Fibrous connective tissue, no invasive carcinoma identified.

FSD: Right retropharyngeal space, biopsy.

- Fibrous connective tissue, no invasive carcinoma identified.

FSE: Right parapharyngeal space, biopsy.

- Fibrous connective tissue, no invasive carcinoma identified.

FSF,F: Larynx and tongue, glossolaryngectomy.

- Invasive squamous cell carcinoma, moderately differentiated, non-keratinizing, at least 4 cm diameter, involving paramidline base of tongue bilaterally, floor of mouth, vallecula, and hyoid bone, without angiolymphatic

[page 2 of 6]
invasion, inked surgical margins not involved.
- Lymph nodes, right cervical - No metastatic carcinoma identified (0/6).

Intraoperative Consult Diagnosis:

An intraoperative frozen section consultation was requested by Dr.

FSA1: Lymph node, pretracheal, biopsy
- One lymph node, no tumor seen

FSB1: Periosteum, mental, biopsy
- No tumor seen

FSC1: Right carotid sheath, biopsy
- No tumor seen, small fragment of nerve present

FSD1: Right retropharyngeal space, biopsy
- No tumor seen

FSE1: Right parapharyngeal space, biopsy
- No tumor seen

Frozen Section Pathologist:

Clinical History:

with a history of moderately differentiated squamous cell carcinoma of the tongue.

Gross Description:

Received are six appropriately labeled containers.

Container A holds a 0.8 x 0.3 x 0.3 cm lymph node candidate; totally submitted in block FSA1, [REDACTED]

Container B holds a 0.8 x 0.4 x 0.2 cm white/tan soft tissue fragment; block FSB1, [REDACTED]

Container C is received fresh in the frozen section room and described as a 1.0 x 0.2 x 0.2 cm red/tan soft tissue fragment which is totally submitted in block FSC1, [REDACTED]

Container D is received in the frozen section room and described as a 0.8 x 0.2 x 0.3 cm red/tan soft tissue

[page 3 of 6]
fragment which is totally submitted in block FSD1, [REDACTED]

Container E is received fresh in the frozen section room and described as a 0.6 x 0.4 x 0.2 cm red/tan soft tissue fragment which is totally submitted in block FSE1, [REDACTED].

Container F:

Specimen fixation: formalin

Type of specimen: total glossectomy and total laryngectomy with partial neck contents from Levels I, II and III

Size of specimen: The tongue measures 7.0 x 6.0 x 2.0 cm and the larynx measures 4.0 x 3.5 x 2.5 cm with two tracheal rings.

Orientation of specimen: The specimen is inked such that the mucosal margin and soft tissue margins on the right are blue, and mucosal margins and soft tissue margins on the left are black. Certain deep and posterior soft tissue margins on the mid line are inked green.

Tumor description: The tumor is a large, ulcerated, destructive lesion measuring 4.0 cm anterior to posterior, 3.1 cm medial to lateral, and 3.0 cm superficial to deep. It is a red, ulcerated destructive lesion involving the posterior right tongue, the base of the tongue bilaterally, the floor of the mouth, palatal glossal arch, and close but not quite involving the vallecula. Multiple Polaroid photographs are taken of the fresh, intact specimen and a ___ solution scan is taken a longitudinal section through the midline of the specimen after fixation.

Location of tumor: see above

Tumor size: see above

Extent of tumor: see above

Presence/absence of bone involvement: The tumor comes very near to the hyoid bone grossly, but involvement cannot be assessed.

Distance of tumor from surgical margins: The tumor comes to within 7.0 cm from the tracheal margin, 1.5 cm from the

[page 4 of 6]
right and left anterior sublingual margins, 0.5 cm from the lateral right lingual margin, 0.4 cm from the posterior right sublingual margin, 1.2 cm from the right aryepiglottic fold margin, 2.5 cm from the left aryepiglottic fold margin, 1.2 cm from the posterior left sublingual margin, 1.1 cm from the lateral left sublingual margin, 1.0 cm from the posterior and deep soft tissue margin, and 1.3 cm from the anterior soft tissue margin, the tumor comes to within 0.5 cm of the lateral right soft tissue margin and 1.4 cm from the lateral left soft tissue margin.

Description of remainder of tissue: unremarkable

Tissue submitted for special investigations: A small amount of tumor and normal is given to Tissue Procurement.

Lymph nodes: The right neck contents consists of six lymph nodes ranging in diameter from 2 mm to 7 mm. Also, there is a 2.5 x 2.5 x 1.0 cm salivary gland with an unremarkable tan, lobulated architecture. The right neck contents contain a single 0.5 cm lymph node candidate.

Block Summary:

F1 - anterior sublingual margin, left
F2 - lateral sublingual margin, left
F3 - posterior sublingual margin, left
F4 - aryepiglottic fold margin, left
F5 - entire tracheal margin
F6 - anterior sublingual margin, right
F7 - lateral sublingual margin, right
F8 - posterior sublingual margin, right
F9 - aryepiglottic fold margin, right
F10 - tumor at posterior tongue
F11 - tumor at base of tongue
F12 - anterior soft tissue margin, contiguous with tissue taken in F11
F13 - deep soft tissue margin, tumor at floor of mouth and hyoid bone
F14 - right vocal cord
F15 - tumor, floor of mouth, vallecula and epiglottis
F16, F17 - full thickness coronal section from superficial to deep at the base of the tongue, including lateral right soft tissue margin
F18 - tumor and lateral soft tissue margin, left

[page 5 of 6]
F19 - tumor at floor of the mouth and right lateral soft tissue margin
F20 - left salivary gland
F21 - three lymph node candidates, left
F22 - three lymph node candidates, left
F23 - one lymph node candidate, right

Light Microscopy:

Light microscopic examination is performed by Dr.

The frozen section diagnoses are confirmed.

Histologic tumor type: squamous carcinoma

Histologic grade: moderately differentiated

Tumor extent: predominantly R paramidline BOT, with extension to FOM, vallecula, and anteriorly to hyoid bone.

Presence/absence of CIS: present.

Presence/absence of angiolymphatic space invasion: absent

Presence/absence of perineural space invasion: absent

Histologic assessment of surgical margins: negative

Lymph nodes: negative

Size of largest nodal metastasis (greatest dimension):

Presence/absence of extranodal extension:

Other significant findings: none.

AJCC staging:

pT4A

pN0

pMx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

Amendment Comment: Following initial case finalization, it

[page 6 of 6]
was brought to our attention that the diagnostic lines do not reference the included lymph nodes.

Source: NCI Genomic Data Commons file 8f50a060-4a48-4563-ade1-78a88802f023 (TCGA-BA-4077.02E24218-B9D7-4184-A290-A6AC7B6C956F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).